Somatic mutation profile of cancer-model specimen HCM-BROD-0138-C25-85B (3D Organoid, passage 9; aliquot HCM-BROD-0138-C25-85B-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0138-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 66.5 years (24,299 days).
Specimen HCM-BROD-0138-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50b6d5e7-c19d-42f9-82e0-e8c855dea6bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0138-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0138-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1525dd14-e106-47ab-9108-237a04517a6a

The open-access MAF lists 151 somatic variants for this specimen: 114 protein-altering or splice-affecting, 30 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 30, Nonsense Mutation 9, Intron 5, Splice Site 3, 3'UTR 2, In Frame Del 2, Splice Region 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 413/566 reads (73%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 232/232 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs377767371, CM041790, COSV61685131, COSV61687710, COSV61689222; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 176/176 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2685+1G>T p.X895_splice | Splice Site (SNP) | VAF 118/228 reads (52%) | catalogued as COSV99714674; called by muse, mutect2
- BCAS3 | c.2771C>A p.P924Q (on ENST00000390652 / NM_001353144.2; = p.P909Q on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 293/294 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV66770793; called by muse, mutect2, varscan2
- BTBD3 | c.1129C>A p.R377S | Missense Mutation (SNP) | VAF 223/478 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54781123, COSV99655857; called by muse, mutect2, varscan2
- CNGB3 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 116/391 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs972916386, COSV60690643; called by muse, mutect2, varscan2
- CSNKA2IP | c.749T>A p.L250H | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV101359565; called by muse, mutect2, varscan2
- DDX27 | c.1601C>T p.T534M | Missense Mutation (SNP) | VAF 77/402 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374365767; called by muse, mutect2, varscan2
- DNAH9 | c.6739-1G>C p.X2247_splice | Splice Site (SNP) | VAF 213/213 reads (100%) | catalogued as COSV52379181; called by muse, mutect2, varscan2
- DTX3 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 124/560 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.737); catalogued as rs12832032; called by mutect2, varscan2
- ENOX2 | c.1209G>T p.E403D (on ENST00000338144 / NM_001382520.1; = p.E374D on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV57648292; called by muse, mutect2, varscan2
- FYB1 | c.919G>T p.G307W | Missense Mutation (SNP) | VAF 142/426 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100686037; called by muse, mutect2, varscan2
- H3-3B | c.17A>C p.Q6P | Missense Mutation (SNP) | VAF 27/295 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV54665787; called by muse, mutect2, varscan2
- HRNR | c.6400G>A p.G2134R | Missense Mutation (SNP) | VAF 90/1386 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.307); catalogued as rs779832642, COSV100913818; called by muse, mutect2
- HYDIN | c.7837G>A p.A2613T | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs201369863, COSV59264388; called by muse, mutect2, varscan2
- JAK2 | c.2657A>G p.H886R | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as rs572395683; called by muse, mutect2, varscan2
- JPH2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 535/881 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs952147058; called by muse, mutect2, varscan2
- KAT6B | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 14/460 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1257245803; called by muse, mutect2
- KDELR2 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760759311; called by muse, mutect2, varscan2
- MAGEB18 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100305603, COSV57463656; called by muse, mutect2, varscan2
- MED26 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 256/408 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54661870, COSV54662422; called by muse, mutect2, varscan2
- METTL25 | c.1586T>A p.I529N | Missense Mutation (SNP) | VAF 137/357 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.048); catalogued as rs1410419115, COSV50258953; called by muse, mutect2, varscan2
- MROH5 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 541/777 reads (70%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs370443826; called by muse, mutect2, varscan2
- MYBPC3 | c.1077G>T p.E359D | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV57032415; called by muse, mutect2, varscan2
- OR11L1 | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV63315046; called by muse, mutect2, varscan2
- PALM3 | c.1879G>T p.G627W (on ENST00000340790; = p.G642W on NM_001145028.2) | Missense Mutation (SNP) | VAF 24/596 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.415); catalogued as rs1314333932; called by muse, mutect2
- PARD3B | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 185/350 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62525340; called by muse, mutect2, varscan2
- PCSK1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 26/498 reads (5%) | catalogued as rs778230512, COSV60734489; called by muse, mutect2
- POU6F2 | c.1604C>A p.P535Q | Missense Mutation (SNP) | VAF 28/465 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.564); catalogued as rs1016001650, COSV68882165; called by muse, mutect2
- PRDX6 | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 134/274 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV61165030; called by muse, mutect2, varscan2
- PSG7 | c.45G>T p.W15C | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV68445394; called by muse, mutect2, varscan2
- RASIP1 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 229/380 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs774923735, COSV55804585; called by muse, mutect2, varscan2
- RBMS3 | c.1051-1G>T p.X351_splice (on ENST00000383767 / NM_001003793.3; = p.X333_splice on NM_001003792.3) | Splice Site (SNP) | VAF 8/152 reads (5%) | catalogued as rs1559825024, COSV99822716; called by muse, mutect2
- RIMS4 | c.42C>G p.F14L | Missense Mutation (SNP) | VAF 136/350 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as COSV65719322, COSV65719408; called by muse, mutect2, varscan2
- SEMA4C | c.2323C>T p.R775W | Missense Mutation (SNP) | VAF 266/521 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs773505484; called by muse, mutect2, varscan2
- SI | c.1960G>T p.A654S | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100016777, COSV52296120; called by muse, mutect2, varscan2
- SLAIN1 | c.1534G>T p.A512S (on ENST00000466548; = p.A249S on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/378 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1364425755; called by muse, mutect2, varscan2
- SLC30A8 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs141202988, COSV69969422; called by muse, mutect2
- SUFU | c.1150T>A p.C384S | Missense Mutation (SNP) | VAF 187/366 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs375419295; called by muse, mutect2, varscan2
- TEX261 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 151/336 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200711339, COSV55537178; called by muse, mutect2, varscan2
- TNIK | c.3602_3604del p.E1201del | In Frame Del (DEL) | VAF 187/538 reads (35%) | catalogued as rs1429342313; called by pindel, varscan2
- TOR3A | c.201C>A p.S67R | Missense Mutation (SNP) | VAF 150/625 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs910095006; called by muse, mutect2, varscan2
- TTYH1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 230/639 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1043754346, COSV56611057; called by muse, mutect2, varscan2
- ZFPM1 | c.1349G>C p.G450A | Missense Mutation (SNP) | VAF 294/446 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as rs200021109; called by mutect2, varscan2
- ZNF33A | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as rs767831049; called by muse, mutect2, varscan2
- ZNF74 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 171/547 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV62621389; called by muse, mutect2, varscan2
- AATK | c.4019C>A p.S1340* (on ENST00000326724 / NM_001080395.3; = p.S1237* on NM_004920.2) | Nonsense Mutation (SNP) | VAF 595/599 reads (99%) | called by muse, mutect2, varscan2
- AP4E1 | c.3311G>T p.C1104F | Missense Mutation (SNP) | VAF 184/396 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ARHGAP10 | c.877T>C p.Y293H | Missense Mutation (SNP) | VAF 106/156 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BCORL1 | c.4777G>T p.E1593* | Nonsense Mutation (SNP) | VAF 58/554 reads (10%) | called by muse, mutect2
- BPTF | c.5477G>T p.R1826L | Missense Mutation (SNP) | VAF 23/287 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CACNA1G | c.1780C>T p.H594Y | Missense Mutation (SNP) | VAF 181/557 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CC2D2A | c.2956G>T p.A986S | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CCDC85B | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 21/747 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.053); called by muse, mutect2
- CFAP70 | c.848T>C p.L283S | Missense Mutation (SNP) | VAF 80/376 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- CHD6 | c.952_957del p.F318_Y319del | In Frame Del (DEL) | VAF 121/243 reads (50%) | called by mutect2, pindel, varscan2
- CNNM1 | c.735C>G p.S245R | Missense Mutation (SNP) | VAF 85/1130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- DENND6A | c.728C>G p.P243R | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.68); called by muse, mutect2
- DUSP6 | c.564dup p.N189Qfs*2 | Frame Shift Ins (INS) | VAF 241/662 reads (36%) | called by mutect2, pindel, varscan2
- E2F1 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 437/804 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPHB1 | c.1364C>A p.P455Q | Missense Mutation (SNP) | VAF 15/502 reads (3%) | SIFT tolerated (1); PolyPhen probably damaging (0.953); called by muse, mutect2
- ERC2 | c.1534C>G p.Q512E | Missense Mutation (SNP) | VAF 204/206 reads (99%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); called by muse, varscan2
- FCSK | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 267/412 reads (65%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- FLNB | c.5216T>A p.M1739K | Missense Mutation (SNP) | VAF 169/169 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- GOLGA6L9 | c.832G>T p.V278L | Missense Mutation (SNP) | VAF 428/1484 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.158); called by muse, varscan2
- GREB1 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 141/249 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- H3C3 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- HECTD2 | c.1569C>A p.F523L | Missense Mutation (SNP) | VAF 202/475 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- IFIT3 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 158/293 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, varscan2
- INSRR | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 25/379 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); called by muse, mutect2
- KDM3B | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 110/353 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LIN7C | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 115/354 reads (32%) | called by muse, mutect2, varscan2
- LMBRD1 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 127/127 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAML3 | c.687G>T p.L229F | Missense Mutation (SNP) | VAF 143/240 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- MAP3K12 | c.1374C>A p.L458= | Splice Region (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- MSRA | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MYH4 | c.2824G>C p.A942P | Missense Mutation (SNP) | VAF 105/313 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- NDUFAF5 | c.631G>T p.G211* | Nonsense Mutation (SNP) | VAF 202/419 reads (48%) | called by muse, mutect2, varscan2
- NIM1K | c.1269C>A p.Y423* | Nonsense Mutation (SNP) | VAF 152/235 reads (65%) | called by muse, mutect2, varscan2
- NPIPB11 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 174/614 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); called by muse, varscan2
- NYNRIN | c.2360C>A p.P787H | Missense Mutation (SNP) | VAF 109/399 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10X1 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 70/322 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- OR52N4 | c.677C>A p.A226E | Missense Mutation (SNP) | VAF 87/385 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- PCDHB14 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 20/401 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); called by muse, mutect2
- PDCD11 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 167/335 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PDE2A | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 132/451 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PEX5L | c.1877C>A p.P626H | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); called by muse, mutect2
- PIGQ | c.433_444dup p.T145_P148dup | In Frame Ins (INS) | VAF 106/454 reads (23%) | called by mutect2, varscan2
- PLA2G4D | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 178/178 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- PLCL1 | c.1311G>T p.M437I | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.216); called by mutect2, varscan2
- POU4F2 | c.1191G>T p.R397S | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PREX1 | c.2410G>T p.A804S | Missense Mutation (SNP) | VAF 212/516 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PTK6 | c.650C>A p.A217D | Missense Mutation (SNP) | VAF 278/462 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- PTPRS | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 204/340 reads (60%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- RALB | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 120/286 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- RFX4 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 196/489 reads (40%) | called by muse, mutect2, varscan2
- RSBN1L | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | called by muse, varscan2
- SCAF1 | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 335/525 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SCX | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 34/1244 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2
- SH3D19 | c.1501G>A p.V501I | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2
- SLC6A1 | c.1758G>T p.Q586H | Missense Mutation (SNP) | VAF 264/264 reads (100%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- SORCS1 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 315/612 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, varscan2
- SOX9 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 61/628 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- SP110 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2
- STIM1 | c.1228C>G p.L410V | Missense Mutation (SNP) | VAF 142/229 reads (62%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TDRD15 | c.5300C>G p.S1767C | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TOX3 | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPC3 | c.1440G>C p.R480S (on ENST00000379645 / NM_001366479.2; = p.R407S on NM_003305.2) | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- UNC80 | c.1731C>A p.F577L | Missense Mutation (SNP) | VAF 165/306 reads (54%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- USH1G | c.1195C>A p.L399M | Missense Mutation (SNP) | VAF 457/457 reads (100%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- VAMP7 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- VWDE | c.2257C>A p.Q753K | Missense Mutation (SNP) | VAF 64/355 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF507 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AP5Z1 | c.468C>A p.V156= | Silent (SNP) | VAF 257/601 reads (43%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.1953G>A p.Q651= | Silent (SNP) | VAF 299/562 reads (53%) | called by muse, mutect2, varscan2
- BCL11A | c.2088G>A p.P696= (on ENST00000335712 / NM_001365609.1; = p.P730= on NM_018014.4) | Silent (SNP) | VAF 245/477 reads (51%) | catalogued as rs770188408, COSV59635551; called by muse, mutect2, varscan2
- BHLHA9 | c.252C>T p.A84= | Silent (SNP) | VAF 728/728 reads (100%) | catalogued as rs776078357, COSV101195467; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4635C>A p.T1545= | Silent (SNP) | VAF 153/245 reads (62%) | called by muse, mutect2, varscan2
- CACNA1E | c.4464C>A p.I1488= | Silent (SNP) | VAF 73/360 reads (20%) | catalogued as COSV62426460; called by muse, mutect2, varscan2
- CARMIL3 | c.2805G>T p.G935= | Silent (SNP) | VAF 42/602 reads (7%) | called by muse, mutect2
- DAO | c.939C>A p.G313= | Silent (SNP) | VAF 126/290 reads (43%) | catalogued as rs755937780; called by muse, mutect2, varscan2
- DCHS1 | c.4923C>T p.D1641= | Silent (SNP) | VAF 352/497 reads (71%) | catalogued as COSV55043079; called by muse, mutect2, varscan2
- DDOST | c.1335C>G p.V445= (on ENST00000415136; = p.V428= on NM_005216.5) | Silent (SNP) | VAF 188/188 reads (100%) | catalogued as COSV58631831; called by muse, mutect2, varscan2
- ELMO1 | c.2007G>C p.L669= | Silent (SNP) | VAF 151/303 reads (50%) | called by muse, mutect2, varscan2
- FRMPD3 | c.4479C>T p.T1493= | Silent (SNP) | VAF 164/165 reads (99%) | called by muse, mutect2, varscan2
- GBE1 | c.120C>A p.P40= | Silent (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- HELZ2 | c.1890C>T p.F630= (on ENST00000467148 / NM_001037335.2; = p.F61= on NM_033405.3) | Silent (SNP) | VAF 491/858 reads (57%) | called by muse, mutect2, varscan2
- KATNIP | c.984A>G p.K328= | Silent (SNP) | VAF 101/309 reads (33%) | called by muse, mutect2, varscan2
- KLHL18 | c.1290C>A p.G430= | Silent (SNP) | VAF 39/224 reads (17%) | called by muse, mutect2, varscan2
- NFKBIE | c.303G>C p.P101= | Silent (SNP) | VAF 104/1416 reads (7%) | called by muse, mutect2
- NIM1K | c.411C>T p.Y137= | Silent (SNP) | VAF 44/447 reads (10%) | catalogued as rs201681485; called by muse, mutect2
- NUMB | c.1893T>G p.T631= (on ENST00000355058; = p.T620= on NM_003744.5) | Silent (SNP) | VAF 110/306 reads (36%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1716C>T p.S572= | Silent (SNP) | VAF 314/472 reads (67%) | catalogued as COSV56475554; called by muse, mutect2, varscan2
- PDE2A | c.2364C>T p.Y788= | Silent (SNP) | VAF 19/190 reads (10%) | catalogued as rs141055431; called by muse, mutect2, varscan2
- SDHA | c.1275G>T p.V425= | Silent (SNP) | VAF 112/298 reads (38%) | called by muse, mutect2, varscan2
- SOX17 | c.726C>T p.P242= | Silent (SNP) | VAF 456/1175 reads (39%) | called by muse, mutect2, varscan2
- TMEM132D | c.867C>T p.S289= | Silent (SNP) | VAF 249/598 reads (42%) | catalogued as rs1437970397, COSV101396482; called by muse, mutect2, varscan2
- TTC14 | c.1188A>G p.E396= | Silent (SNP) | VAF 15/372 reads (4%) | called by muse, mutect2
- USP51 | c.534C>A p.G178= | Silent (SNP) | VAF 229/229 reads (100%) | called by muse, mutect2, varscan2
- WDFY3 | c.8727G>A p.E2909= | Silent (SNP) | VAF 135/224 reads (60%) | catalogued as rs1459832537; called by muse, mutect2, varscan2
- WFIKKN1 | c.999C>A p.G333= | Silent (SNP) | VAF 64/629 reads (10%) | called by muse, mutect2, varscan2
- ZMYM1 | c.1359A>G p.S453= | Silent (SNP) | VAF 149/149 reads (100%) | called by muse, mutect2, varscan2
- ZNF793 | c.603G>A p.P201= | Silent (SNP) | VAF 181/269 reads (67%) | catalogued as rs756721872; called by muse, mutect2, varscan2
- ATP10B | c.470+996C>A | Intron (SNP) | VAF 89/311 reads (29%) | called by muse, mutect2, varscan2
- ATP6V1F | c.159-201C>T | Intron (SNP) | VAF 198/412 reads (48%) | called by muse, mutect2, varscan2
- CLASP1 | c.196-647C>G | Intron (SNP) | VAF 168/336 reads (50%) | catalogued as rs367638364; called by muse, mutect2, varscan2
- LCE1A | c.*75C>A | 3'UTR (SNP) | VAF 28/399 reads (7%) | called by muse, mutect2
- NDUFAF6 | c.*396G>T | 3'UTR (SNP) | VAF 146/456 reads (32%) | called by mutect2, varscan2
- RPS6 | c.138+37G>C | Intron (SNP) | VAF 32/217 reads (15%) | called by muse, mutect2, varscan2
- TPK1 | c.185+15104C>A | Intron (SNP) | VAF 19/196 reads (10%) | catalogued as COSV100765150; called by muse, mutect2, varscan2
